HCMI case HCM-STAN-1277-C55 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Uterus, NOS. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/6784de63-5d64-4203-9e17-336202359820

Demographics
Sex at birth: female; Ethnicity: not hispanic or latino; Days to birth: -24,813 days (67.9 years before the index date); Year of birth: 1947; Vital status: Dead; Days to death: 660 days (1.8 years).

Diagnoses (1)
1. Carcinosarcoma, NOS: ICD-O-3 morphology code: 8980/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Classification of tumor: primary; AJCC staging edition: 8th; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage IIIC1; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Peritoneal fluid cytological status: Non-Malignant; Sites of involvement: Cervix / Pelvic Lymph Node(s) / Ovary, Right / Ovary, Left / Fallopian Tube, Right / Fallopian Tube, Left / Uterus / Parametrium, Left / Parametrium, Right.
   Pathology details: Lymph node involvement: Positive; Lymphatic invasion present: Yes; Tumor largest dimension diameter: 7 cm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 39 days; Days to treatment end: 252 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Fallopian tube; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Pelvic lymph nodes; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Ovary; Days to progression: 0 days.
- Days to follow up: 652 days (1.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- MLH1 (IHC): Positive.
- MLH1 hypermethylation: Equivocal.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PIK3CA mutation, nos: Positive; Amino-acid change: G106V.
- PMS2 (IHC): Positive.
- PTEN mutation, nos: Negative.
- TP53 mutation, nos: Negative.
- Test (Microsatellite Analysis): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 96 kg; Height: 168 cm; BMI: 34.
- Timepoint category: Prior to Diagnosis; Hormone replacement therapy type: Progesterone and Estrogen.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-STAN-1277-C55-11B: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample HCM-STAN-1277-C55-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
